TCGA case TCGA-B6-A0IB — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/157ec9e0-ca6e-4da1-9233-f976cf0db433

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Dead; Days to death: 3,941 days (10.8 years).

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.7 years (23,646 days); Year of diagnosis: 1992; Method of diagnosis: Biopsy; AJCC staging edition: 3rd; AJCC pathologic T: T3; AJCC pathologic N: N3; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Skin / Breast, Right Upper Inner / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 8; Lymph nodes tested: 15; Micrometastasis present: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 72.2 years (26,363 days); Days to diagnosis: 2,717 days (7.4 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS to Locoregional Site, for recurrent disease.

Follow-up (2 entries)
- Day 2,717 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 2,717 days (7.4 years).
- Days to follow up: 3,941 days (10.8 years); Disease response: With Tumor.

Molecular and laboratory tests
- ESR1 (IHC): Positive.
- PGR (IHC): Positive.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B6-A0IB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-B6-A0IB-01A-01-BSA: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-B6-A0IB-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-B6-A0IB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B6-A0IB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Indeterminate (neither Pre or Postmenopausal); Micromet detection by IHC: No; Margin status: Negative; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Biopsy, NOS; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Inner Quadrant; Anatomic organ subdivision: Right.
- First nonlymph node metastasis anatomic sites: Metastasis site: Skin.
- Follow-up form: Tumor status: With tumor; New tumor event type: Distant Metastasis; New tumor event site other: lung, bone, liver; New tumor event surgery: No; New tumor event er positivity other scale: fmol/mg; New tumor event er positivity define method: image cytometry; New tumor event pr positivity other scale: fmol/mg; New tumor event pr positivity define method: image cytometry.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 3,941 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 3,941 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,717 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B6-A0IB-01A-11D-A036-01): tumor purity 0.74, ploidy 3.06, whole-genome doublings 1.
